Somatic mutation profile of tumor specimen ALCH-B1IP-TTP1-A (aliquot ALCH-B1IP-TTP1-A-2-0-D-A76C-36) from ALCHEMIST case ALCH-B1IP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.1 years (20,120 days).
Specimen ALCH-B1IP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aa55e0f-dd55-4e0d-b89e-f96c769bc85c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1IP-NB1-A (Blood Derived Normal), aliquot ALCH-B1IP-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17255780-633c-4a46-aa74-ad889d08b200

The open-access MAF lists 826 somatic variants for this specimen: 556 protein-altering or splice-affecting, 162 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 483, Silent 162, Intron 49, Nonsense Mutation 36, RNA 28, Splice Site 14, Frame Shift Del 12, 3'UTR 11, 5'UTR 9, Splice Region 9, 5'Flank 7, 3'Flank 4.

Variants (750 of 826; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 72/363 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 29/102 reads (28%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58052864; called by muse, mutect2, varscan2
- ABTB1 | c.1405G>T p.D469Y (on ENST00000232744 / NM_172027.3; = p.D327Y on NM_032548.3) | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV51743342; called by muse, mutect2, varscan2
- ACTG2 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.919); catalogued as rs770461467; called by muse, mutect2, varscan2
- ADAM19 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.216); catalogued as COSV57436629; called by muse, mutect2, varscan2
- ADAMTS1 | c.1833G>T p.E611D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs747518739; called by muse, mutect2, varscan2
- ADAMTS2 | c.2568C>A p.Y856* | Nonsense Mutation (SNP) | VAF 48/223 reads (22%) | catalogued as COSV52363091; called by muse, mutect2, varscan2
- ADGRA3 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99031860, COSV99293816; called by muse, mutect2, varscan2
- ADGRL2 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 120/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780393998; called by muse, mutect2, varscan2
- ALMS1 | c.5974C>T p.H1992Y | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52512269; called by muse, mutect2, varscan2
- ANK1 | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); catalogued as rs200597167; called by muse, mutect2
- ANK2 | c.2926G>T p.A976S | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs977347770; called by muse, mutect2, varscan2
- ANK2 | c.8260G>C p.A2754P | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.113); catalogued as rs1167202865; called by muse, mutect2, varscan2
- AP5B1 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs770220741; called by muse, mutect2, varscan2
- ASB15 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 132/334 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216642394, COSV99306574; called by muse, mutect2, varscan2
- ASB5 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs753072074; called by muse, mutect2, varscan2
- ASXL3 | c.4077G>C p.L1359F | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs1162815494, COSV52474863; called by muse, mutect2
- ATP10D | c.2483A>G p.Q828R | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1165585596, COSV99906170; called by muse, mutect2, varscan2
- ATRNL1 | c.3955G>T p.V1319F | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100373365; called by muse, mutect2, varscan2
- CAB39 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV51475363; called by muse, mutect2, varscan2
- CACNA1B | c.4820C>A p.A1607D | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53155202; called by muse, mutect2, varscan2
- CARNMT1 | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as rs1294641167, COSV100961656; called by muse, mutect2, varscan2
- CD8A | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as COSV52157269; called by muse, mutect2, varscan2
- CEP128 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53674745; called by muse, mutect2, varscan2
- CFAP54 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.203); catalogued as rs138697359; called by muse, mutect2, varscan2
- CHD1 | c.4285A>G p.K1429E | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52339500; called by muse, mutect2
- CHTF18 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50100228, COSV99135559; called by muse, mutect2, varscan2
- CNTN6 | c.601A>G p.K201E | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63168760; called by muse, mutect2, varscan2
- CPNE1 | c.1040del p.P347Lfs*11 (on ENST00000352393; = p.P352Lfs*11 on NM_003915.5) | Frame Shift Del (DEL) | VAF 50/262 reads (19%) | catalogued as rs1214264641; called by mutect2, pindel, varscan2
- CRYGC | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1054047596, COSV56408873; called by muse, mutect2, varscan2
- CYFIP1 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs768106871; called by muse, mutect2, varscan2
- DDHD1 | c.1082A>G p.Q361R (on ENST00000323669; = p.Q558R on NM_030637.3) | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs199607183; called by muse, mutect2, varscan2
- DOCK7 | c.4174A>T p.M1392L (on ENST00000635253 / NM_001367561.1; = p.M1361L on NM_033407.3) | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as rs763190572; called by muse, mutect2, varscan2
- DPF3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.334); catalogued as COSV63499709; called by muse, mutect2
- E2F2 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757615854; called by muse, mutect2, varscan2
- EPHA5 | c.2509G>T p.G837* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV56640216; called by muse, mutect2
- ERBB4 | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100727283; called by muse, mutect2, varscan2
- ERBB4 | c.2518G>T p.V840F | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61493011; called by muse, mutect2, varscan2
- ERN1 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs372670758, COSV101458488; called by muse, mutect2, varscan2
- EXT1 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM099176; called by muse, mutect2, varscan2
- EYS | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV60997571; called by muse, mutect2, varscan2
- FABP2 | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56788375; called by muse, mutect2, varscan2
- FBLN2 | c.3437G>T p.R1146L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776129342; called by muse, mutect2, varscan2
- FBXO42 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1001861789; called by muse, mutect2, varscan2
- FLT3 | c.2471T>A p.V824E | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV104385722; called by muse, mutect2
- G3BP2 | c.751A>T p.S251C | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1261313799; called by muse, mutect2, varscan2
- GIP | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100656919; called by muse, mutect2, varscan2
- GLB1L2 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 59/166 reads (36%) | catalogued as COSV60279915; called by muse, mutect2, varscan2
- GLDN | c.1255G>C p.A419P | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV59090441; called by muse, mutect2, varscan2
- GNAS | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV58348640; called by muse, mutect2, varscan2
- GPLD1 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015582; called by muse, mutect2, varscan2
- GPR26 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.209); catalogued as rs1261317128, COSV52934492; called by muse, mutect2, varscan2
- GPR65 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50862925; called by muse, mutect2, varscan2
- GPX5 | c.441A>T p.K147N | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV101297286; called by muse, mutect2
- GRB10 | c.1371G>T p.E457D (on ENST00000398812; = p.E411D on NM_001001549.3) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100241360, COSV60010006; called by muse, mutect2, varscan2
- GREB1 | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 184/433 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104375013; called by muse, mutect2, varscan2
- GREM2 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100547925; called by muse, mutect2, varscan2
- GRIN2A | c.3329C>A p.S1110* | Nonsense Mutation (SNP) | VAF 68/166 reads (41%) | catalogued as COSV100409997; called by muse, varscan2
- GRM3 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862664, COSV100862746; called by muse, mutect2, varscan2
- HAO1 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66493319; called by muse, mutect2, varscan2
- HEPACAM2 | c.947G>T p.C316F (on ENST00000394468 / NM_001039372.4; = p.C304F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV100506811; called by muse, mutect2, varscan2
- HUNK | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54231687; called by muse, mutect2, varscan2
- HUWE1 | c.4462G>T p.V1488L | Missense Mutation (SNP) | VAF 97/233 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as rs1556975520; called by muse, mutect2, varscan2
- IFNA2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as rs1267763666, COSV66505662; called by muse, mutect2, varscan2
- IGF1 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV61033976; called by muse, mutect2, varscan2
- IGHV3-64 | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 234/400 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); catalogued as rs782705314; called by muse, mutect2, varscan2
- JAG1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 17/171 reads (10%) | catalogued as COSV54762794; called by muse, mutect2, varscan2
- KCNA1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV66836712; called by muse, mutect2, varscan2
- KCNJ3 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV54544954; called by muse, mutect2, varscan2
- KIAA0753 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 81/490 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376555002, COSV63818529; called by muse, mutect2, varscan2
- KIF15 | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV58158930, COSV58161787; called by muse, mutect2, varscan2
- KIF1A | c.646C>A p.R216S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM157165, COSV57482306; called by muse, mutect2, varscan2
- KIR3DL2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1176208000; called by muse, mutect2, varscan2
- KLHL14 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as COSV63833912; called by muse, mutect2, varscan2
- KLHL2 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as COSV99899883; called by muse, mutect2, varscan2
- KRT33B | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52441255; called by muse, mutect2, varscan2
- KRTAP5-11 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.389); catalogued as COSV99063472; called by muse, mutect2, varscan2
- LAMA3 | c.7250C>A p.S2417Y (on ENST00000313654 / NM_198129.4; = p.S808Y on NM_000227.6) | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV99334489; called by muse, mutect2, varscan2
- LIN28A | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV54263098, COSV99575302; called by muse, mutect2, varscan2
- MAGEB2 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66780546; called by muse, mutect2, varscan2
- MAML1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99483052, COSV99483470; called by muse, mutect2, varscan2
- MDGA2 | c.2053G>A p.E685K (on ENST00000399232 / NM_001113498.2; = p.E387K on NM_182830.4) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.46); catalogued as COSV62106345; called by muse, mutect2, varscan2
- MED13 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750747647; called by muse, varscan2
- MEIS2 | c.827G>C p.R276P (on ENST00000561208 / NM_170675.5; = p.R263P on NM_002399.3) | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV54933573, COSV54944315; called by muse, mutect2, varscan2
- MFHAS1 | c.1644G>C p.E548D | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99360008; called by muse, mutect2
- MLF2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs919387499, COSV52571386; called by muse, mutect2, varscan2
- MLH3 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs770819541, COSV53154757; called by muse, mutect2
- MRPS30 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50181773; called by muse, varscan2
- MS4A14 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55730221; called by muse, mutect2, varscan2
- MTREX | c.2837C>T p.S946L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1338638309; called by muse, mutect2, varscan2
- MUC17 | c.4894C>A p.L1632I | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100075111; called by muse, mutect2, varscan2
- MXD3 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57462977; called by muse, mutect2
- MYH13 | c.3563A>T p.Q1188L | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99354829; called by muse, mutect2, varscan2
- MYH4 | c.3196G>T p.A1066S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55125276; called by muse, mutect2, varscan2
- NADSYN1 | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59810211; called by muse, mutect2, varscan2
- NES | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs1475551386, COSV100957846; called by muse, mutect2, varscan2
- NOTCH1 | c.4893C>G p.I1631M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.429); catalogued as COSV53053829, COSV53067115; called by muse, mutect2, varscan2
- NPHS1 | c.1096A>T p.S366C | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990954; called by muse, mutect2, varscan2
- NPY | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54215620; called by muse, mutect2, varscan2
- NR3C2 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs765471749; called by muse, mutect2, varscan2
- NRAP | c.4227G>C p.E1409D (on ENST00000359988 / NM_001322945.2; = p.E1374D on NM_006175.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.787); catalogued as COSV63490925; called by mutect2, varscan2
- NRK | c.695G>C p.R232P | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as COSV54601789; called by muse, mutect2, varscan2
- NRXN3 | c.1301G>T p.G434V (on ENST00000335750 / NM_001330195.2; = p.G61V on NM_004796.6) | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59730360; called by muse, mutect2, varscan2
- OOSP2 | c.347+1G>T p.X116_splice | Splice Site (SNP) | VAF 35/66 reads (53%) | catalogued as COSV53929501, COSV99613696; called by muse, mutect2, varscan2
- OR14K1 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 125/180 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV51721143, COSV99315167; called by muse, mutect2, varscan2
- OR1L3 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1173122938; called by muse, mutect2, varscan2
- OR4D2 | c.800T>C p.M267T | Missense Mutation (SNP) | VAF 213/511 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV73459795; called by muse, mutect2, varscan2
- OR4K17 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs768218908; called by muse, varscan2
- OR51A7 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1282128297, COSV63788516; called by muse, mutect2, varscan2
- OR6N1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58647694; called by muse, mutect2, varscan2
- OR7A5 | c.920G>T p.W307L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1340781770; called by muse, mutect2, varscan2
- PAPPA2 | c.3830C>A p.A1277E | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs774497756; called by muse, mutect2, varscan2
- PATE2 | c.303T>A p.C101* | Nonsense Mutation (SNP) | VAF 50/182 reads (27%) | catalogued as COSV62069574; called by muse, mutect2, varscan2
- PCDH10 | c.2909G>C p.R970P | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52095799; called by muse, mutect2, varscan2
- PCDHA4 | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as COSV63545495; called by muse, mutect2, varscan2
- PCDHB4 | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV52023446; called by muse, mutect2, varscan2
- PGK2 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV100505719; called by muse, mutect2, varscan2
- PIP | c.249C>G p.N83K | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1447043170, COSV52120579; called by muse, mutect2, varscan2
- PKD2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1416456167; called by muse, mutect2, varscan2
- PKP1 | c.1586C>A p.P529H | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1366886599; called by muse, mutect2, varscan2
- PLEKHG5 | c.301G>A p.A101T (on ENST00000400915 / NM_001042663.3; = p.A64T on NM_020631.6) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1160064455; called by mutect2, varscan2
- PNKP | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV55587728; called by muse, mutect2, varscan2
- PNLIPRP2 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs782008175; called by muse, mutect2, varscan2
- PRAMEF12 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); catalogued as COSV100742978; called by muse, mutect2, varscan2
- PRDM9 | c.610+1G>A p.X204_splice | Splice Site (SNP) | VAF 288/582 reads (49%) | catalogued as rs780759190, COSV99691239; called by muse, mutect2, varscan2
- PRR23B | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61494378, COSV61494900; called by muse, mutect2, varscan2
- PSG4 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs765786331; called by muse, mutect2, varscan2
- PTK7 | c.2264A>C p.Q755P | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100029885; called by muse, mutect2, varscan2
- PTPRM | c.2949G>T p.W983C | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141406581, COSV59857751, COSV59858155; called by muse, mutect2
- PTPRM | c.3392G>T p.R1131L | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100155864, COSV100158822; called by muse, mutect2, varscan2
- PUDP | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs758819525, COSV66904877; called by muse, mutect2, varscan2
- RAG2 | c.1262C>A p.P421H | Missense Mutation (SNP) | VAF 235/647 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.859); catalogued as COSV57557319, COSV57559055; called by muse, mutect2, varscan2
- RBM47 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs1432459776, COSV55932982, COSV99921231; called by muse, mutect2, varscan2
- RNF122 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as rs1054030786, COSV56359615; called by muse, mutect2, varscan2
- RNF213 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60621986; called by muse, mutect2, varscan2
- RPS6KA6 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53118766; called by muse, mutect2, varscan2
- RSPO4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.147); catalogued as rs748638528; called by muse, mutect2, varscan2
- RTRAF | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1324603866; called by muse, mutect2, varscan2
- RXFP2 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV53638285; called by muse, mutect2, varscan2
- RYR1 | c.6419G>T p.R2140L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV62093789, COSV62113663; called by muse, mutect2, varscan2
- SALL1 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs758644081, COSV51759161; called by muse, mutect2, varscan2
- SALL2 | c.595A>G p.M199V | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1315909351; called by muse, mutect2, varscan2
- SCART1 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV100741493; called by muse, mutect2, varscan2
- SCN2A | c.2187del p.W729Cfs*9 | Frame Shift Del (DEL) | VAF 59/293 reads (20%) | catalogued as COSV51843103; called by mutect2, pindel, varscan2
- SEPTIN12 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as COSV99190722; called by muse, mutect2, varscan2
- SEPTIN12 | c.203C>A p.T68K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51618951; called by muse, mutect2, varscan2
- SIM1 | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV53496942; called by muse, mutect2, varscan2
- SLC14A2 | c.2258G>A p.G753D | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1382651856; called by muse, mutect2, varscan2
- SLC22A12 | c.957C>A p.V319= | Splice Region (SNP) | VAF 40/138 reads (29%) | catalogued as COSV60573037; called by muse, mutect2, varscan2
- SLC8A1 | c.2815G>T p.G939W | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60475247; called by muse, mutect2, varscan2
- SLC9A2 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52130613; called by muse, mutect2, varscan2
- SLITRK1 | c.789del p.N265Tfs*61 | Frame Shift Del (DEL) | VAF 46/209 reads (22%) | catalogued as COSV65677606; called by mutect2, pindel, varscan2
- SMG1 | c.3928G>T p.D1310Y | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1344498769; called by muse, mutect2, varscan2
- SNTG2 | c.1570G>T p.G524C | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.304); catalogued as COSV57992509; called by muse, mutect2, varscan2
- SQSTM1 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.081); catalogued as COSV62435358; called by muse, mutect2, varscan2
- SRGAP3 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs372381347; called by muse, mutect2
- ST14 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs772387882; called by muse, mutect2, varscan2
- STARD9 | c.11812C>T p.P3938S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as rs986340987; called by muse, mutect2, varscan2
- STK36 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009091796; called by muse, mutect2, varscan2
- SYT3 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58895825; called by muse, mutect2, varscan2
- TANC2 | c.4708G>T p.V1570F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.017); catalogued as COSV67336227; called by muse, mutect2, varscan2
- TAS1R2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64745670; called by muse, mutect2, varscan2
- TBX4 | c.1241C>A p.P414Q | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as COSV53607261; called by muse, mutect2, varscan2
- TECTA | c.6352G>A p.G2118S | Missense Mutation (SNP) | VAF 89/328 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.818); catalogued as rs774547226; called by muse, mutect2, varscan2
- TENT5D | c.1078A>G p.R360G | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57637223; called by muse, mutect2, varscan2
- TEX15 | c.2389A>T p.S797C (on ENST00000256246; = p.S1180C on NM_001350162.2) | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99820637; called by muse, mutect2, varscan2
- TICAM1 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV50234879; called by muse, mutect2, varscan2
- TMEM132E | c.526C>A p.H176N (on ENST00000321639; = p.H266N on NM_001304438.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs547524578; called by muse, mutect2, varscan2
- TMEM207 | c.19T>C p.F7L | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs1272703718; called by muse, mutect2, varscan2
- TMEM63B | c.1609C>T p.L537= | Splice Region (SNP) | VAF 49/160 reads (31%) | catalogued as COSV99440811; called by muse, mutect2, varscan2
- TNN | c.576C>A p.Y192* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV53424824; called by muse, mutect2, varscan2
- TP53 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as CM035961, COSV53163407; called by muse, mutect2, varscan2
- TRBV4-2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 72/604 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs374910682; called by muse, varscan2
- TRIM48 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 73/493 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs769284668, COSV101338303, COSV70161649; called by muse, mutect2, varscan2
- TRIM48 | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 71/490 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs374540164; called by muse, mutect2, varscan2
- TRIP4 | c.1173G>T p.W391C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56033344; called by muse, mutect2, varscan2
- TRUB1 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53930846; called by muse, mutect2, varscan2
- TUBA3E | c.539C>G p.A180G | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV56058586, COSV56058591; called by muse, mutect2, varscan2
- UHRF1BP1L | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768676656; called by muse, varscan2
- UMOD | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM136330, COSV100208375; called by muse, mutect2, varscan2
- UNC5A | c.378C>G p.C126W | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56166930; called by muse, mutect2, varscan2
- UNC5D | c.632G>T p.R211M | Missense Mutation (SNP) | VAF 77/197 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs138754011; called by muse, mutect2, varscan2
- VCAM1 | c.1920G>T p.E640D | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.314); catalogued as COSV99658829; called by muse, mutect2, varscan2
- VSTM2A | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as rs1034859487; called by muse, mutect2, varscan2
- WBP2 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as rs1237449021; called by muse, mutect2
- XIRP2 | c.5985G>T p.M1995I (on ENST00000628543; = p.M2170I on NM_152381.6) | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54737398; called by muse, mutect2, varscan2
- XYLT1 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1360763258; called by muse, mutect2, varscan2
- YARS1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as rs778008635; called by muse, mutect2, varscan2
- ZAN | c.5633C>A p.P1878Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV61811848; called by muse, mutect2, varscan2
- ZGRF1 | c.5691G>T p.M1897I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1167533031; called by muse, mutect2, varscan2
- ZGRF1 | c.2758G>C p.A920P | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.85); catalogued as COSV52203797; called by muse, mutect2, varscan2
- ZNF229 | c.1283C>A p.T428K | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99349946; called by muse, varscan2
- ZNF257 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs777459042, COSV101448053; called by muse, mutect2, varscan2
- ZNF317 | c.1773G>T p.W591C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); catalogued as rs1326672433, COSV56111533; called by muse, mutect2, varscan2
- ZNF468 | c.1254A>T p.K418N | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749058874, COSV99700470; called by muse, mutect2, varscan2
- ZNF486 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV58721104; called by muse, mutect2, varscan2
- ZNF672 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60639344; called by muse, mutect2, varscan2
- ZNF772 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs771011227, COSV100582836; called by muse, mutect2, varscan2
- AADAT | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCA13 | c.3179C>T p.T1060I | Missense Mutation (SNP) | VAF 70/393 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ABCA6 | c.2740+2T>A p.X914_splice | Splice Site (SNP) | VAF 77/187 reads (41%) | called by muse, mutect2, varscan2
- ABCC1 | c.2213G>C p.R738T | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ABCC2 | c.3320T>C p.L1107P | Missense Mutation (SNP) | VAF 20/666 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ABCD2 | c.1679A>C p.Q560P | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG4 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC136428.1 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAMTS17 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS5 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS8 | c.625A>G p.S209G | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.3481C>T p.R1161* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3474G>T p.W1158C (on ENST00000506720 / NM_001322402.2; = p.W1090C on NM_015236.6) | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFAP1L1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGL | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGMO | c.692G>A p.C231Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AL121899.2 | c.1806G>T p.E602D | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.7598A>T p.K2533M | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD20A2P | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by mutect2, varscan2
- ANKRD30A | c.3909A>T p.Q1303H (on ENST00000611781; = p.Q1247H on NM_052997.2) | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ANKRD30B | c.938C>G p.T313R | Missense Mutation (SNP) | VAF 175/473 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ANO6 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ARHGEF18 | c.1069G>T p.V357F (on ENST00000359920 / NM_001130955.2; = p.V253F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF33 | c.1866C>G p.I622M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ARHGEF4 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF4 | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ASTL | c.1097T>A p.L366Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.367); called by muse, mutect2
- BANF2 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BICD2 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- BRINP3 | c.1352C>G p.T451R | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BRIX1 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 134/584 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BSN | c.11356G>T p.G3786W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTBD7 | c.2920G>T p.G974C | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf105 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CA6 | c.925T>A p.*309Rext*11 | Nonstop Mutation (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2
- CACNA2D1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CALM2 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 47/335 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMK2B | c.276-2A>G p.X92_splice | Splice Site (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- CBARP | c.531G>T p.E177D (on ENST00000382477; = p.E157D on NM_152769.3) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCBE1 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 210/554 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC144A | c.3513G>C p.K1171N | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CCDC33 | c.890T>A p.M297K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CCDC93 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CDH12 | c.1538C>G p.A513G | Missense Mutation (SNP) | VAF 12/363 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- CDH12 | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH4 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CENPC | c.886A>C p.T296P | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, varscan2
- CEP128 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP47 | c.2659T>C p.W887R | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP61 | c.1842C>A p.Y614* | Nonsense Mutation (SNP) | VAF 84/220 reads (38%) | called by muse, mutect2, varscan2
- CLCA1 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLCC1 | c.895-1G>T p.X299_splice (on ENST00000356970 / NM_001377464.1; = p.X249_splice on NM_015127.5) | Splice Site (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- CLK4 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL4A2 | c.2200C>A p.P734T | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- COL6A6 | c.3196C>G p.Q1066E | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPA4 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CRYGB | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- CSMD1 | c.8774G>T p.G2925V (on ENST00000520002; = p.G2924V on NM_033225.6) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CST8 | c.231+1del | Frame Shift Del (DEL) | VAF 36/156 reads (23%) | called by mutect2, pindel, varscan2
- CWH43 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP19A1 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2F1 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CYP2F1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DCAKD | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- DCLK2 | c.2158C>A p.P720T | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DEPTOR | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 78/148 reads (53%) | called by muse, mutect2, varscan2
- DMRTA2 | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- DNAH3 | c.2926C>A p.L976I | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.8915A>G p.E2972G | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNM1 | c.2387G>T p.R796L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DRAXIN | c.387G>A p.W129* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- DSG2 | c.1406T>A p.I469N | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DSG3 | c.1432A>G p.T478A | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- DUSP13 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1078A>T p.K360* | Nonsense Mutation (SNP) | VAF 48/78 reads (62%) | called by muse, mutect2, varscan2
- EEF2 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EGF | c.941-1G>T p.X314_splice | Splice Site (SNP) | VAF 78/296 reads (26%) | called by muse, mutect2, varscan2
- EMCN | c.752-1G>T p.X251_splice | Splice Site (SNP) | VAF 70/216 reads (32%) | called by muse, mutect2, varscan2
- EMILIN1 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ENPP2 | c.2262del p.K754Nfs*63 (on ENST00000075322 / NM_001040092.3; = p.K806Nfs*63 on NM_006209.5) | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- EP400 | c.6983A>G p.D2328G | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPPK1 | c.4297C>T p.P1433S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ERGIC2 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ERV3-1 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERVV-2 | c.1178C>A p.A393E | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EYS | c.7097C>A p.S2366* | Nonsense Mutation (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- FAM135A | c.259A>T p.M87L (on ENST00000370479 / NM_001351599.1; = p.M44L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FAM155A | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM71E2 | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM98A | c.144G>T p.W48C | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- FBN1 | c.7424T>C p.I2475T | Missense Mutation (SNP) | VAF 30/1011 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); called by muse, mutect2
- FBXL7 | c.791T>A p.L264Q | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.154); called by muse, mutect2
- FCGRT | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FER1L6 | c.3454G>C p.A1152P | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FHOD3 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FIBCD1 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- FLG2 | c.6301A>T p.R2101W | Missense Mutation (SNP) | VAF 181/435 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FLT3 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 38/223 reads (17%) | called by muse, mutect2, varscan2
- FLT4 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FLT4 | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FLT4 | c.1108A>T p.K370* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | called by muse, varscan2
- FMO1 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2
- FRMPD2 | c.3907A>T p.R1303* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | called by mutect2, varscan2
- FSCB | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- FSHR | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRG3 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALM | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCC1 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GCKR | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- GPR158 | c.1176C>G p.C392W | Missense Mutation (SNP) | VAF 94/441 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR87 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPRASP2 | c.842G>T p.W281L | Missense Mutation (SNP) | VAF 110/187 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN2B | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM6 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRM8 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GSE1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSG1L2 | c.90C>G p.H30Q | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- GUCY1A2 | c.1473_1474del p.D492Sfs*9 | Frame Shift Del (DEL) | VAF 65/172 reads (38%) | called by mutect2, pindel, varscan2
- HCN1 | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN1 | c.2141C>A p.A714D | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HDAC9 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HELZ2 | c.2765G>A p.G922E (on ENST00000467148 / NM_001037335.2; = p.G353E on NM_033405.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, varscan2
- HFM1 | c.3159del p.A1054Lfs*10 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- HID1 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HOXA2 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPB1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HSPH1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HUNK | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV2D-29 | c.350T>A p.I117K | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGSF9 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL17F | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ING3 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- INPP4B | c.2150T>A p.V717E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ISLR2 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH5 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ITM2C | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR2 | c.7733C>T p.S2578L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- JAG2 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KATNAL1 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- KCNA4 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- KCNC4 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KCNH2 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- KCP | c.3323G>T p.C1108F (on ENST00000620378; = p.C1232F on NM_001366122.1) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- KERA | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLHL17 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KLHL23 | c.1538C>G p.T513S | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- KLHL9 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 166/260 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP4-4 | c.57C>G p.N19K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KRTAP5-11 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LANCL3 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAX1 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 120/281 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LRFN5 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LRP12 | c.658T>A p.F220I | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRRC26 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC7 | c.653T>C p.M218T (on ENST00000651989 / NM_001370785.2; = p.M185T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LZTR1 | c.962G>T p.W321L | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MALRD1 | c.4698G>C p.M1566I | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MALRD1 | c.5046G>T p.E1682D | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MANBA | c.1397C>T p.A466V (on ENST00000642252; = p.A420V on NM_005908.4) | Missense Mutation (SNP) | VAF 101/399 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MBL2 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- MC2R | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 155/364 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MEGF8 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MGAT5 | c.1314C>G p.H438Q | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- MGAT5B | c.1169G>T p.R390M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MIGA1 | c.1275+4A>G | Splice Region (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- MLNR | c.203A>T p.D68V | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MMP12 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2
- MMP8 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 136/247 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL11 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MRPS30 | c.1031-1G>T p.X344_splice | Splice Site (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- MUC12 | c.3206C>A p.T1069N (on ENST00000379442; = p.T926N on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MUC12 | c.3954C>A p.H1318Q (on ENST00000379442; = p.H1175Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 156/457 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- MUC16 | c.29171C>T p.T9724I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC16 | c.11849C>T p.T3950I | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); called by muse, mutect2
- MUC2 | c.2569C>A p.H857N | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MXD3 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- MYH4 | c.1701G>C p.Q567H | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2
- MYH4 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MYH6 | c.3430G>T p.E1144* | Nonsense Mutation (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- MYH8 | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 107/549 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYLK3 | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MYO16 | c.4064C>A p.P1355H | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYO7A | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 139/269 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYT1L | c.674T>A p.M225K | Missense Mutation (SNP) | VAF 93/414 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NCOR1 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NEXMIF | c.2862A>T p.Q954H | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.346); called by muse, mutect2
- NFASC | c.2657C>A p.T886K (on ENST00000339876 / NM_001378329.1; = p.T989K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- NFATC3 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- NGEF | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NIN | c.4327A>C p.K1443Q | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2
- NLGN2 | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- NLRP13 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOX4 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPTX2 | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR4A3 | c.819G>C p.E273D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRAP | c.3533G>T p.G1178V (on ENST00000359988 / NM_001322945.2; = p.G1143V on NM_006175.4) | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRG1 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NTM | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP153 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 131/609 reads (22%) | called by muse, mutect2, varscan2
- NUP35 | c.904-5A>T | Splice Region (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- NUTM2G | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NYNRIN | c.3191A>T p.Y1064F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OCLN | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OLAH | c.389C>A p.A130E (on ENST00000378228 / NM_001039702.3; = p.A183E on NM_018324.3) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- OPLAH | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPRPN | c.726del p.K242Nfs*22 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- OR13C5 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR2A12 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR2L5 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 164/290 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR2T2 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- OR2V2 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR4D10 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR51C1P | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR52A5 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- OR52D1 | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.101); called by muse, mutect2
- OR52K1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR5AP2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- OR5L2 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOF | c.1618T>C p.Y540H | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA3 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, varscan2
- PABPC1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPC4L | c.1098G>T p.L366F | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- PALM | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- PAPOLB | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PAPPA | c.2951T>C p.I984T | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PCDH11X | c.2157C>A p.N719K | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCDH15 | c.4674G>T p.W1558C (on ENST00000644397 / NM_001354429.2; = p.W1500C on NM_001142771.2) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PCDH18 | c.986T>A p.L329* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- PCDH8 | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PCDHA7 | c.1928_1939del p.P643_R646del | In Frame Del (DEL) | VAF 32/118 reads (27%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.517A>T p.N173Y | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PCDHGB6 | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.10720G>T p.D3574Y | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCLO | c.9340A>T p.T3114S | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PCNX2 | c.4415G>T p.C1472F | Missense Mutation (SNP) | VAF 162/328 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PEG3 | c.4219G>C p.E1407Q | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PGK1 | c.1118G>C p.G373A | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF21B | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PIF1 | c.1278C>A p.C426* | Nonsense Mutation (SNP) | VAF 55/252 reads (22%) | called by muse, mutect2, varscan2
- PIK3C2G | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.487); called by muse, mutect2
- PIWIL4 | c.2521C>G p.P841A | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1L1 | c.6298C>G p.L2100V | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PLCG2 | c.2751G>T p.M917I | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PLEC | c.8794G>T p.G2932C (on ENST00000322810 / NM_201380.4; = p.G2822C on NM_000445.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- POGZ | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2
- POTEI | c.2340T>A p.D780E | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.164); called by muse, mutect2
- POU2F1 | c.14C>A p.S5* (on ENST00000541643 / NM_001365848.1; = p.S28* on NM_002697.4) | Nonsense Mutation (SNP) | VAF 43/239 reads (18%) | called by muse, mutect2, varscan2
- PPEF2 | c.533-2A>G p.X178_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- PPP1R12B | c.2490G>T p.W830C | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PRAMEF12 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRPF6 | c.2611G>C p.D871H | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PRRT4 | c.1506C>A p.H502Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PSMB10 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 87/188 reads (46%) | called by muse, mutect2, varscan2
- PTAFR | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTPRD | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 92/346 reads (27%) | called by muse, mutect2, varscan2
- PTX4 | c.292C>T p.Q98* (on ENST00000447419 / NM_001328608.2; = p.Q93* on NM_001013658.1) | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | called by muse, mutect2, varscan2
- RABGAP1L | c.2176A>T p.N726Y | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, varscan2
- RAD21 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- RALGAPA1 | c.1920A>C p.E640D | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM33 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- RFPL3 | c.17_18del p.L6Rfs*4 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- RGL2 | c.768+8C>T | Splice Region (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- RGS11 | c.887G>C p.R296P (on ENST00000397770 / NM_183337.3; = p.R275P on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- RHOC | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS1 | c.2834G>T p.R945I | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RIOX2 | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- RNASE2 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.087); called by muse, mutect2
- RNF213 | c.2282G>T p.W761L | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPIA | c.738+1G>T p.X246_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | called by muse, varscan2
- RPS6KA2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUFY3 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- SAG | c.76-1G>T p.X26_splice | Splice Site (SNP) | VAF 71/376 reads (19%) | called by muse, mutect2, varscan2
- SBK1 | c.569T>A p.V190E | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SDC1 | c.765G>T p.G255= | Splice Region (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SERPINA11 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SERPINB2 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SFMBT2 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SGK3 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SHISA9 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 106/171 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SIGLEC1 | c.4797C>A p.D1599E | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SIGLECL1 | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIN3A | c.3222G>T p.Q1074H | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SIX5 | c.2169G>T p.K723N | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC10A2 | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 132/373 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SLC12A7 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC18A2 | c.134del p.P45Qfs*52 | Frame Shift Del (DEL) | VAF 29/53 reads (55%) | called by mutect2, pindel*, varscan2
- SLC25A42 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- SLC2A9 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- SLC2A9 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SLC5A2 | c.1281-5C>T | Splice Region (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- SLC6A17 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SLCO5A1 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SOX6 | c.898+1G>T p.X300_splice | Splice Site (SNP) | VAF 104/222 reads (47%) | called by muse, mutect2, varscan2
- SPAG16 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA16 | c.699del p.K233Nfs*9 | Frame Shift Del (DEL) | VAF 114/271 reads (42%) | called by mutect2, pindel, varscan2
- SPATA31E1 | c.1468C>A p.L490I | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SPEN | c.1607A>G p.H536R | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIDR | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.135); called by muse, mutect2
- SRMS | c.1337C>G p.P446R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRRM2 | c.7498G>T p.G2500W | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- STARD9 | c.2433C>A p.S811R | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- STK17B | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STON2 | c.2386G>T p.V796L (on ENST00000649389 / NM_001366849.2; = p.V739L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- STRA8 | c.661G>A p.E221K (on ENST00000275764; = p.E199K on NM_182489.2) | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- SYN2 | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SYNE1 | c.2419C>T p.L807F (on ENST00000367255 / NM_182961.4; = p.L814F on NM_033071.3) | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SYNPO | c.1470G>T p.Q490H (on ENST00000394243 / NM_001166208.2; = p.Q246H on NM_007286.6) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYPL2 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAAR5 | c.77_78del p.R26Nfs*54 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | called by mutect2, pindel, varscan2
- TAMM41 | c.388A>T p.I130F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TANC2 | c.1828C>A p.L610M | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBC1D4 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- TCP11L1 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TFCP2L1 | c.366G>C p.W122C | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TMEM151A | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFSF9 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, varscan2
- TNXB | c.9764G>T p.G3255V (on ENST00000647633; = p.G3008V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- TRBV4-2 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 77/612 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TRIM75P | c.573C>G p.N191K | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM1 | c.4104G>T p.Q1368H | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TRPM7 | c.5249C>T p.A1750V | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TRUB1 | c.555T>G p.I185M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TSPAN16 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 143/195 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TTC19 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TTN | c.29056G>C p.G9686R (on ENST00000591111; = p.G8759R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.28114A>T p.T9372S (on ENST00000591111; = p.T8445S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.22454G>T p.S7485I (on ENST00000591111; = p.S6558I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/101 reads (9%) | PolyPhen benign (0.168); called by muse, mutect2
- TTN | c.12581C>G p.S4194* (on ENST00000591111; = p.S4148* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 54/262 reads (21%) | called by muse, mutect2, varscan2
- TXK | c.1580G>T p.W527L | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); called by muse, mutect2
- UBXN2A | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- UGT2B4 | c.1062C>A p.Y354* | Nonsense Mutation (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- UMOD | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.14330G>T p.G4777V | Missense Mutation (SNP) | VAF 102/582 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP22 | c.691-1G>A p.X231_splice | Splice Site (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- VPS16 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VWA3A | c.1719T>G p.S573R | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WAPL | c.-22A>G | Splice Region (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- WDFY4 | c.3042G>T p.Q1014H | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- YLPM1 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB7B | c.796G>T p.G266C (on ENST00000292176; = p.G300C on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZBTB8B | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZDBF2 | c.6574A>C p.K2192Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZDHHC9 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 196/348 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ZFAND4 | c.185-1G>T p.X62_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- ZFP57 | c.1216C>G p.H406D | Missense Mutation (SNP) | VAF 140/694 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZIC4 | c.430T>A p.C144S | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ZNF285 | c.1461A>T p.E487D | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, varscan2
- ZNF423 | c.1838C>A p.P613Q (on ENST00000563137 / NM_001379286.1; = p.P605Q on NM_015069.4) | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF573 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ZNF677 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF724 | c.1420G>T p.G474* | Nonsense Mutation (SNP) | VAF 198/314 reads (63%) | called by muse, mutect2, varscan2
- ZNF729 | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 160/263 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF804A | c.374A>T p.K125M | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF831 | c.4962G>C p.M1654I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.182); called by muse, mutect2
- ZNF865 | c.2998G>T p.D1000Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZNF92 | c.610G>T p.E204* (on ENST00000328747 / NM_152626.4; = p.E135* on NM_007139.4) | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- ACTB | c.51C>T p.C17= | Silent (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
- AHCTF1 | c.1014G>T p.L338= (on ENST00000366508; = p.L312= on NM_015446.5) | Silent (SNP) | VAF 142/266 reads (53%) | catalogued as COSV58253777; called by muse, mutect2, varscan2
- ALDH5A1 | c.1323G>A p.G441= | Silent (SNP) | VAF 161/384 reads (42%) | catalogued as rs1329061888; called by muse, mutect2, varscan2
- ALKAL1 | c.358T>C p.L120= | Silent (SNP) | VAF 43/200 reads (22%) | called by muse, mutect2, varscan2
- AMBP | c.231G>T p.A77= | Silent (SNP) | VAF 56/113 reads (50%) | catalogued as COSV54323593; called by muse, mutect2, varscan2
- ANKIB1 | c.831G>T p.P277= | Silent (SNP) | VAF 161/564 reads (29%) | called by muse, mutect2, varscan2
- APBA1 | c.972G>T p.R324= | Silent (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2
- ARHGAP11A | c.2433A>T p.I811= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.1068G>T p.L356= (on ENST00000359920 / NM_001130955.2; = p.L252= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/182 reads (38%) | called by muse, mutect2, varscan2
- ATG9B | c.1788C>T p.H596= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs749356751; called by mutect2, varscan2
- ATP2B3 | c.2175G>T p.G725= | Silent (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- ATXN7L2 | c.1443C>T p.T481= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- BCAM | c.1659C>A p.A553= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs751271346, COSV54304847; called by muse, mutect2, varscan2
- BCL6B | c.789G>A p.V263= | Silent (SNP) | VAF 28/168 reads (17%) | called by muse, mutect2, varscan2
- BDNF | c.147C>A p.P49= | Silent (SNP) | VAF 112/171 reads (65%) | called by muse, mutect2, varscan2
- CACNA1C | c.2601T>A p.L867= | Silent (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- CACNG5 | c.591G>T p.V197= | Silent (SNP) | VAF 35/227 reads (15%) | catalogued as rs753837304, COSV50057220; called by muse, mutect2, varscan2
- CADM3 | c.465T>G p.S155= (on ENST00000368125 / NM_001127173.3; = p.S189= on NM_021189.5) | Silent (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- CAPN12 | c.636C>A p.G212= | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- CDH8 | c.1461G>T p.L487= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV54861977, COSV54901567; called by muse, mutect2, varscan2
- CDHR2 | c.1536G>T p.A512= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs114954087, COSV99992119; called by muse, mutect2, varscan2
- CDKN2B | c.210G>T p.A70= | Silent (SNP) | VAF 180/293 reads (61%) | catalogued as COSV52805675; called by muse, mutect2, varscan2
- CELSR3 | c.7119C>T p.S2373= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2
- CEP170B | c.1659G>A p.L553= (on ENST00000453495; = p.L482= on NM_015005.3) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1185304710; called by muse, varscan2
- CFAP221 | c.348C>T p.G116= | Silent (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- CHRM2 | c.858C>G p.S286= | Silent (SNP) | VAF 55/431 reads (13%) | called by muse, mutect2, varscan2
- CMSS1 | c.783G>A p.L261= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs761443718; called by muse, mutect2, varscan2
- COL25A1 | c.1275C>A p.A425= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV101211618; called by muse, mutect2, varscan2
- COL6A1 | c.2760G>T p.L920= | Silent (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- CR1 | c.4338A>T p.S1446= | Silent (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- CTU1 | c.168G>T p.V56= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- DDX59 | c.1326C>G p.L442= | Silent (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- DHX34 | c.186C>G p.T62= | Silent (SNP) | VAF 40/316 reads (13%) | catalogued as rs756079909; called by muse, mutect2, varscan2
- DISP1 | c.2412C>T p.P804= | Silent (SNP) | VAF 197/399 reads (49%) | catalogued as rs1419395968; called by muse, mutect2, varscan2
- EDIL3 | c.21C>A p.V7= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- EFTUD2 | c.2178G>C p.L726= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ERAL1 | c.210G>T p.L70= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- ERC1 | c.2907A>G p.V969= (on ENST00000360905 / NM_178040.4; = p.V941= on NM_178039.4) | Silent (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- ESYT3 | c.1587G>A p.L529= | Silent (SNP) | VAF 73/194 reads (38%) | called by muse, mutect2, varscan2
- EWSR1 | c.144T>A p.T48= | Silent (SNP) | VAF 143/276 reads (52%) | called by muse, mutect2, varscan2
- EXTL1 | c.906C>A p.R302= | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- FAM131B | c.762G>T p.G254= | Silent (SNP) | VAF 86/277 reads (31%) | called by muse, mutect2, varscan2
- FAM83B | c.1323C>A p.A441= | Silent (SNP) | VAF 55/198 reads (28%) | catalogued as COSV100174332; called by muse, mutect2, varscan2
- FAR2 | c.852C>T p.L284= | Silent (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- FCRL3 | c.1995C>A p.I665= | Silent (SNP) | VAF 88/186 reads (47%) | called by muse, mutect2, varscan2
- FRG2C | c.705C>T p.V235= | Silent (SNP) | VAF 113/500 reads (23%) | called by muse, varscan2
- FRMD5 | c.543G>A p.T181= | Silent (SNP) | VAF 93/159 reads (58%) | catalogued as rs750273320; called by muse, mutect2, varscan2
- FRZB | c.393G>C p.P131= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV54553831; called by muse, mutect2, varscan2
- FSIP2 | c.9051T>A p.S3017= | Silent (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- FZD5 | c.771C>T p.F257= | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- GALK1 | c.262C>T p.L88= | Silent (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- GFOD1 | c.549G>A p.L183= | Silent (SNP) | VAF 87/253 reads (34%) | called by muse, mutect2, varscan2
- GPR174 | c.711G>T p.G237= | Silent (SNP) | VAF 20/102 reads (20%) | called by mutect2, varscan2
- HCN4 | c.1533C>A p.G511= | Silent (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- HEMGN | c.1230T>A p.T410= | Silent (SNP) | VAF 151/340 reads (44%) | called by muse, mutect2, varscan2
- HHIPL1 | c.486G>T p.L162= | Silent (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- HOXB6 | c.258G>A p.S86= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- HRC | c.60G>T p.L20= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- HS6ST1 | c.120G>C p.L40= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- IFIH1 | c.1143G>A p.L381= | Silent (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- IGFBP1 | c.714G>A p.R238= | Silent (SNP) | VAF 58/277 reads (21%) | called by muse, mutect2, varscan2
- IGSF11 | c.684G>T p.L228= (on ENST00000393775 / NM_001015887.3; = p.L227= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/178 reads (51%) | called by muse, mutect2, varscan2
- IPO5 | c.9G>T p.A3= | Silent (SNP) | VAF 101/238 reads (42%) | catalogued as rs1244990263; called by muse, mutect2, varscan2
- ITGA8 | c.1791A>G p.L597= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs906228158; called by mutect2, varscan2
- JAK3 | c.468C>G p.L156= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- KCNB1 | c.2289G>A p.E763= | Silent (SNP) | VAF 18/327 reads (6%) | called by muse, mutect2
- KCND2 | c.240T>C p.T80= | Silent (SNP) | VAF 252/714 reads (35%) | catalogued as rs1289280023, COSV100474976; called by muse, mutect2, varscan2
- KCNG1 | c.1024C>T p.L342= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs747211852; called by muse, mutect2, varscan2
- KIAA1217 | c.1119C>G p.V373= | Silent (SNP) | VAF 79/450 reads (18%) | called by muse, mutect2, varscan2
- KL | c.984C>T p.A328= | Silent (SNP) | VAF 63/337 reads (19%) | called by muse, mutect2, varscan2
- KLHL30 | c.1077C>T p.P359= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs747247377; called by muse, mutect2, varscan2
- KRTAP19-2 | c.9T>C p.Y3= | Silent (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- L1CAM | c.3393C>A p.I1131= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- LAPTM5 | c.594C>A p.V198= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV99612736; called by muse, mutect2, varscan2
- LILRA1 | c.39G>C p.L13= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs780169638; called by muse, mutect2, varscan2
- LILRB1 | c.1767A>G p.T589= (on ENST00000427581; = p.T539= on NM_006669.6) | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- LRATD1 | c.150C>A p.P50= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs764712944, COSV99707023; called by muse, mutect2, varscan2
- LRP1B | c.1701C>T p.T567= | Silent (SNP) | VAF 30/273 reads (11%) | catalogued as rs1488089248, COSV104431994; called by muse, mutect2, varscan2
- LRP1B | c.1194C>T p.D398= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as rs967993720; called by muse, mutect2
- LRRC8C | c.513C>T p.T171= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- LRWD1 | c.786A>T p.A262= | Silent (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- MCRIP2 | c.39G>T p.A13= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- MGAM2 | c.4848C>A p.I1616= | Silent (SNP) | VAF 98/316 reads (31%) | called by muse, mutect2, varscan2
- MGAT4C | c.261T>C p.Y87= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs937081464; called by muse, mutect2
- MRC1 | c.129C>A p.A43= | Silent (SNP) | VAF 244/667 reads (37%) | catalogued as rs781852223; called by muse, mutect2, varscan2
- MRPS17 | c.210T>A p.P70= | Silent (SNP) | VAF 30/405 reads (7%) | called by muse, mutect2
- MUC16 | c.37941C>A p.G12647= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs75995954, COSV67470890, COSV67493606; called by muse, mutect2, varscan2
- MUC16 | c.6462A>T p.S2154= | Silent (SNP) | VAF 38/118 reads (32%) | called by muse, mutect2, varscan2
- MUC17 | c.3321T>A p.P1107= | Silent (SNP) | VAF 65/394 reads (16%) | called by muse, mutect2, varscan2
- MYO3A | c.2247G>T p.V749= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV56353938; called by muse, mutect2
- NACAD | c.252G>T p.A84= | Silent (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- NDE1 | c.984G>C p.A328= (on ENST00000577101; = p.G301R on NM_017668.3) | Silent (SNP) | VAF 75/152 reads (49%) | called by muse, mutect2, varscan2
- NIM1K | c.51C>A p.A17= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- NLGN2 | c.1119C>T p.F373= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- NOBOX | c.606C>A p.A202= | Silent (SNP) | VAF 35/279 reads (13%) | called by muse, mutect2, varscan2
- NRG4 | c.243C>T p.F81= | Silent (SNP) | VAF 81/154 reads (53%) | called by muse, mutect2, varscan2
- NRM | c.36C>T p.L12= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV99223596; called by muse, mutect2
- OLFM1 | c.897G>A p.S299= (on ENST00000371793 / NM_001282611.2; = p.S281= on NM_014279.5) | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as rs141686389, COSV53276595; called by muse, mutect2, varscan2
- OR14J1 | c.648C>T p.Y216= | Silent (SNP) | VAF 10/308 reads (3%) | catalogued as rs775271065; called by muse, mutect2
- OR1D5 | c.483C>T p.F161= | Silent (SNP) | VAF 72/545 reads (13%) | called by muse, mutect2, varscan2
- OR2T2 | c.795C>T p.S265= | Silent (SNP) | VAF 34/358 reads (9%) | called by muse, mutect2, varscan2
- OR4L1 | c.375C>T p.A125= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- OR5T3 | c.138C>T p.I46= | Silent (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- OR5T3 | c.297A>C p.A99= | Silent (SNP) | VAF 101/180 reads (56%) | called by muse, mutect2, varscan2
- OR6B1 | c.390C>G p.L130= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV68770102; called by muse, mutect2, varscan2
- OR9Q2 | c.309C>A p.L103= | Silent (SNP) | VAF 48/309 reads (16%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1827G>T p.G609= | Silent (SNP) | VAF 39/228 reads (17%) | called by muse, mutect2, varscan2
- PAQR9 | c.528G>T p.L176= | Silent (SNP) | VAF 44/66 reads (67%) | called by muse, mutect2, varscan2
- PCARE | c.1884C>A p.A628= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV59058749; called by muse, mutect2, varscan2
- PCDHA8 | c.1005C>A p.T335= | Silent (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- PCK1 | c.1146C>A p.T382= | Silent (SNP) | VAF 102/346 reads (29%) | called by muse, varscan2
- PIK3R6 | c.1113C>T p.G371= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2
- PKHD1L1 | c.5109A>T p.L1703= | Silent (SNP) | VAF 100/276 reads (36%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.3024C>T p.Y1008= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- PLK3 | c.1701C>G p.V567= | Silent (SNP) | VAF 36/307 reads (12%) | called by muse, mutect2, varscan2
- POTEF | c.765C>A p.A255= | Silent (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- POTEH | c.282C>G p.L94= | Silent (SNP) | VAF 56/390 reads (14%) | catalogued as rs769567881, COSV100625301; called by muse, varscan2
- PRAMEF18 | c.171G>A p.Q57= | Silent (SNP) | VAF 94/724 reads (13%) | called by muse, varscan2
- PRDM9 | c.1554C>A p.I518= | Silent (SNP) | VAF 155/620 reads (25%) | called by muse, mutect2, varscan2
- PROCR | c.525G>T p.R175= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV53825215; called by muse, mutect2, varscan2
- PRSS38 | c.252C>A p.V84= | Silent (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- PTPN13 | c.3738T>C p.S1246= (on ENST00000411767 / NM_080683.3; = p.S1227= on NM_006264.3) | Silent (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- R3HCC1 | c.771G>T p.G257= (on ENST00000411463; = p.G217= on NM_001136108.3) | Silent (SNP) | VAF 30/146 reads (21%) | called by muse, mutect2, varscan2
- REG1A | c.303C>A p.G101= | Silent (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- RHCG | c.742C>A p.R248= | Silent (SNP) | VAF 88/196 reads (45%) | called by muse, mutect2, varscan2
- RIPOR3 | c.1641G>A p.R547= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- RYR1 | c.4209C>A p.A1403= | Silent (SNP) | VAF 27/116 reads (23%) | called by muse, mutect2, varscan2
- SBK1 | c.570A>C p.V190= | Silent (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- SLC16A13 | c.225G>A p.T75= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV57274117; called by muse, mutect2
- SLC26A7 | c.900C>T p.P300= | Silent (SNP) | VAF 78/171 reads (46%) | catalogued as rs760305330; called by muse, mutect2, varscan2
- SLC2A14 | c.1248C>G p.L416= | Silent (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- SLC2A3 | c.807C>T p.P269= | Silent (SNP) | VAF 106/252 reads (42%) | called by muse, mutect2, varscan2
- SLC34A2 | c.1311G>T p.T437= | Silent (SNP) | VAF 67/465 reads (14%) | called by muse, mutect2, varscan2
- SLC7A1 | c.1587C>G p.V529= | Silent (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- SLC8A3 | c.381G>T p.R127= | Silent (SNP) | VAF 52/278 reads (19%) | called by muse, mutect2, varscan2
- SMOC2 | c.454C>A p.R152= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV62443855; called by muse, mutect2, varscan2
- SPANXN3 | c.249G>A p.K83= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- SPATA5 | c.363G>T p.V121= | Silent (SNP) | VAF 57/173 reads (33%) | called by muse, mutect2, varscan2
- STOML3 | c.69G>T p.R23= | Silent (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- TACO1 | c.447C>T p.L149= | Silent (SNP) | VAF 48/425 reads (11%) | called by muse, mutect2, varscan2
- TKTL2 | c.1572C>T p.D524= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as rs1441583883, COSV54921721; called by muse, mutect2, varscan2
- TMCO6 | c.105G>A p.R35= | Silent (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- TMEM201 | c.507G>T p.A169= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as rs1319179663, COSV61052968; called by muse, mutect2, varscan2
- TNFRSF13C | c.90C>T p.R30= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- TRBC2 | c.249G>T p.S83= | Silent (SNP) | VAF 61/244 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.99711T>A p.T33237= (on ENST00000591111; = p.T25813= on NM_003319.4) | Silent (SNP) | VAF 50/256 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.52854G>T p.A17618= (on ENST00000591111; = p.A10194= on NM_003319.4) | Silent (SNP) | VAF 32/632 reads (5%) | called by muse, mutect2
- TUBB4A | c.933G>T p.L311= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs200310489; called by muse, mutect2, varscan2
- TXNDC2 | c.741C>A p.I247= (on ENST00000306084 / NM_001098529.2; = p.I180= on NM_032243.6) | Silent (SNP) | VAF 66/289 reads (23%) | called by muse, mutect2, varscan2
- UNC13C | c.618C>T p.S206= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV52874889; called by muse, varscan2
- UNC13C | c.4758C>A p.T1586= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as COSV99511549; called by muse, mutect2, varscan2
- VWA5B1 | c.2769C>A p.A923= (on ENST00000375079; = p.A924= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- VWC2 | c.531G>C p.P177= | Silent (SNP) | VAF 68/173 reads (39%) | catalogued as rs528790694, COSV61491001; called by muse, mutect2, varscan2
- WASL | c.1128G>T p.P376= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV56136218; called by muse, mutect2, varscan2
- WWP2 | c.33G>T p.V11= | Silent (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- ZBTB46 | c.201G>A p.S67= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs567479339; called by muse, mutect2, varscan2
- ZFHX4 | c.8601T>A p.S2867= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV50535592; called by muse, mutect2, varscan2
- ZNF229 | c.1326C>T p.F442= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs200478914, COSV99351011; called by muse, varscan2
- ZNF658 | c.2937A>T p.S979= | Silent (SNP) | VAF 107/271 reads (39%) | called by muse, mutect2, varscan2
- ZNF735 | c.204G>T p.L68= | Silent (SNP) | VAF 126/441 reads (29%) | called by muse, mutect2, varscan2
- ZNF835 | c.162C>T p.R54= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV73379163; called by muse, mutect2, varscan2
- ZSCAN21 | c.495C>T p.P165= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as rs1296266100; called by muse, mutect2, varscan2
- AC073310.1 | n.867G>T | RNA (SNP) | VAF 16/56 reads (29%) | catalogued as rs750547738; called by muse, mutect2, varscan2
- AC093155.3 | c.767-760A>T | Intron (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14155G>A | Intron (SNP) | VAF 43/119 reads (36%) | called by muse, mutect2, varscan2
- ACTN2 | c.1840-10G>T | Intron (SNP) | VAF 187/363 reads (52%) | catalogued as COSV63978061; called by muse, mutect2, varscan2
- ADAM3A | n.1784G>T | RNA (SNP) | VAF 55/252 reads (22%) | catalogued as rs1188361226; called by muse, mutect2, varscan2
- ADCY1 | c.1605+2167G>T | Intron (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- AL450442.1 | n.602C>G | RNA (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- AL590617.2 | n.1606G>C | RNA (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- ALAS2 | c.-15-1825C>A | Intron (SNP) | VAF 64/151 reads (42%) | called by muse, mutect2, varscan2
- ALOX12 | c.1641+40G>A | Intron (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- ANP32B | c.*1G>T | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505240 C>T | 5'Flank (SNP) | VAF 8/180 reads (4%) | catalogued as rs1234271569; called by muse, mutect2
- AREL1 | chr14:74713082 del C | 5'Flank (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF10L | c.*368G>A | 3'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916470 G>T | 5'Flank (SNP) | VAF 31/57 reads (54%) | catalogued as COSV58120837, COSV58125529; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2981G>T | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- BMERB1 | c.107-12977G>T | Intron (SNP) | VAF 100/252 reads (40%) | called by muse, mutect2, varscan2
- BOC | c.667+153C>T | Intron (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- BPI | c.613-713C>A | Intron (SNP) | VAF 51/190 reads (27%) | called by muse, mutect2, varscan2
- BRD9 | c.718-56G>T | Intron (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- C5orf60 | n.2346C>A | RNA (SNP) | VAF 51/277 reads (18%) | called by muse, mutect2, varscan2
- C5orf67 | n.629C>A | RNA (SNP) | VAF 36/263 reads (14%) | called by muse, mutect2, varscan2
- CCDC89 | chr11:85682822 G>A | 3'Flank (SNP) | VAF 111/359 reads (31%) | called by muse, mutect2, varscan2
- CDC42 | c.105+185A>G | Intron (SNP) | VAF 82/204 reads (40%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2375G>T | 3'UTR (SNP) | VAF 57/409 reads (14%) | called by muse, mutect2, varscan2
- CLEC18B | c.877+16G>T | Intron (SNP) | VAF 15/104 reads (14%) | called by muse, varscan2
- COG3 | c.*4G>T | 3'UTR (SNP) | VAF 15/103 reads (15%) | called by mutect2, varscan2
- CPLANE1 | c.*5426G>T | 3'UTR (SNP) | VAF 26/670 reads (4%) | called by muse, mutect2
- DAW1 | c.973+5105C>A | Intron (SNP) | VAF 77/223 reads (35%) | catalogued as COSV59363830; called by muse, mutect2, varscan2
- DBF4B | c.1189+869_1189+873del | Intron (DEL) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- DCD | c.290-178G>T | Intron (SNP) | VAF 117/208 reads (56%) | catalogued as rs1284529388; called by muse, mutect2, varscan2
- DCHS2 | n.4977C>A | RNA (SNP) | VAF 55/218 reads (25%) | called by muse, mutect2, varscan2
76 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 76 other) are not listed here.
